Surgical pathology report (de-identified scan), TCGA case TCGA-69-7763, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-7763-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] M

SPECIMEN SUBMITTED:

Part A: RIGHT MIDDLE LOBE

Part B: #7

Part C: #8

Part D: #11

Part E: #10

Final Diagnosis

1. Right lung, middle lobe, lobectomy (A) Adenocarcinoma, mixed type with papillary, bronchioloalveolar and acinar patterns..
- Four (4) peribronchiolar lymph nodes with anthracosis, negative for neoplasm.
2. Lymph nodes, #7, #8, #11, #10 (B-E) - Benign anthracotic lymph nodes.

Diagnosis Comment:

Tumor Location: Right middle lobe

Tumor Size: 2.1 x 1.2 x 0.5 cm

Vascular Invasion: Absent

Lymphatic Invasion: Absent

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Negative

Pleura/Soft Tissue Margin: Negative

Pathologic Stage (AJCC): pT1b N0 M0: Stage IA

Intraoperative Diagnosis:

- A. Bronchial margin is negative and tumor is adenocarcinoma.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis:

SECONDARY MALIGNANT NEOPLASM RIGHT LUNG

Gross Description:

A. Received fresh for frozen section consultation is a specimen labeled "right middle lobe". The specimen consists of a right middle lobectomy measuring 11.0 x 10.0 x 4.0 cm. The specimen weighs 75 grams pre-fixation. The bronchial remnant measures 0.4 cm in length. The pleural surface appears smooth and glistening. A staple line of resection is present measuring 12 cm in length. The stapled margin is inked orange. The specimen is serially sectioned perpendicular to the parenchymal line of resection to reveal a yellow firm palpable mass measuring 2.1 x 1.2 x 0.5 cm. The central area demonstrates a focal area of necrosis. The mass extends to within 0.5 cm of the pleural surface, 1.5 cm from the bronchial margin, and 1.2 cm from the nearest parenchymal line of resection. No other gross abnormalities are identified. The bronchus does not appear to be involved by neoplasm. The remaining lung parenchyma appears tan-pink and unremarkable. No focal areas of consolidation or emphysematous changes are present. Representative sections are submitted as follows: A1 bronchial shave margin, A2 random section of tumor, A3 vascular margin, A4 mass with nearest parenchymal line of resection, A5 mass with adjacent vessel, A6-A8 remainder of mass in relationship to pleural surface, A9 peripheral section to mass, A10 proximal section to mass, A11 lymph nodes totally submitted.

B. Received fresh on Telfa gauze labeled [REDACTED] are multiple irregular shaped segments of tan-gray soft tissue aggregating to 0.8 x 0.4 x 0.3 cm. The specimen is totally submitted in formalin in one cassette.

C. Received fresh on Telfa gauze labeled [REDACTED] are multiple irregular shaped segments of tan-gray soft tissue aggregating to 0.7 x 0.6 x 0.3 cm. The specimen is totally submitted in formalin in one cassette.

D. Received fresh on Telfa gauze labeled [REDACTED] are multiple irregular shaped segments of tan-gray soft tissue aggregating to 0.8 x 0.5 x 0.4 cm. The specimen is totally submitted in formalin in one cassette.

E. Received fresh on Telfa gauze labeled [REDACTED] are multiple irregular shaped segments of tan-gray soft tissue aggregating to 1.2 x 1.2 x 0.6 cm. The specimen is totally submitted in formalin in one cassette.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 214dfcb1-cdc6-41dc-8573-e912ecd17704 (TCGA-69-7763.C1AF94B6-BECB-493D-BFAC-2367F2E69490.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).